Somatic mutation profile of cancer-model specimen HCM-BROD-0108-C25-85E (3D Organoid, passage 9; aliquot HCM-BROD-0108-C25-85E-01D-A83U-36), derived from the primary tumor of HCMI case HCM-BROD-0108-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 66.7 years (24,349 days).
Specimen HCM-BROD-0108-C25-85E: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 9.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0f6fc47-64d0-4a00-b6ea-4059a983ed95.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0108-C25-10A (Blood Derived Normal), aliquot HCM-BROD-0108-C25-10A-01D-A83U-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/78415f41-9d59-4d8e-9ba2-2f1bf5de3581

The open-access MAF lists 56 somatic variants for this specimen: 45 protein-altering or splice-affecting, 10 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 38, Silent 10, Nonsense Mutation 2, Frame Shift Del 2, In Frame Del 2, Intron 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>T p.G12V | Missense Mutation (SNP) | VAF 392/594 reads (66%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.517G>T p.V173L | Missense Mutation (SNP) | VAF 534/535 reads (100%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.827); catalogued as rs876660754, CM070299, COSV52676535, COSV52677795, COSV52695723, COSV52823354; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACSL6 | c.877G>A p.V293M (on ENST00000379240; = p.V318M on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 124/377 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0.18); catalogued as rs375566990; called by muse, mutect2, varscan2
- AMY2A | c.112G>A p.D38N | Missense Mutation (SNP) | VAF 169/368 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs754651162; called by muse, mutect2, varscan2
- ATG14 | c.1279G>A p.E427K | Missense Mutation (SNP) | VAF 254/457 reads (56%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs541092841; called by muse, mutect2, varscan2
- CACNA1C | c.6538G>A p.G2180R (on ENST00000399634 / NM_001167625.1; = p.G2109R on NM_000719.7) | Missense Mutation (SNP) | VAF 269/1391 reads (19%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.087); catalogued as rs1455199573, COSV59751926; called by muse, mutect2, varscan2
- CD163L1 | c.253G>A p.V85M | Missense Mutation (SNP) | VAF 187/657 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.703); catalogued as rs370414180; called by muse, mutect2, varscan2
- CEP85 | c.1165C>T p.R389* | Nonsense Mutation (SNP) | VAF 192/297 reads (65%) | catalogued as rs1219250605; called by muse, mutect2, varscan2
- FAT4 | c.10340G>T p.G3447V | Missense Mutation (SNP) | VAF 88/322 reads (27%) | SIFT tolerated (0.97); PolyPhen possibly damaging (0.806); catalogued as COSV58708544; called by muse, mutect2, varscan2
- ICE1 | c.1994C>A p.S665Y | Missense Mutation (SNP) | VAF 91/328 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.094); catalogued as COSV56829757; called by muse, mutect2, varscan2
- INKA1 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 523/734 reads (71%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs144163564; called by muse, mutect2, varscan2
- NEIL2 | c.433G>A p.D145N | Missense Mutation (SNP) | VAF 130/369 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.118); catalogued as rs750916537, COSV52707078; called by muse, mutect2, varscan2
- NYAP1 | c.959C>G p.P320R | Missense Mutation (SNP) | VAF 145/928 reads (16%) | SIFT tolerated (0.39); PolyPhen probably damaging (0.939); catalogued as COSV55721366; called by muse, mutect2, varscan2
- OR2T34 | c.709G>A p.A237T | Missense Mutation (SNP) | VAF 318/1263 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs746667499, COSV60899605, COSV60900803; called by muse, mutect2, varscan2
- OR52H1 | c.458G>A p.R153Q (on ENST00000322653; = p.R159Q on NM_001005289.1) | Missense Mutation (SNP) | VAF 197/615 reads (32%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.595); catalogued as rs571302036, COSV59504840; called by muse, mutect2, varscan2
- PCNX1 | c.3330del p.F1110Lfs*7 | Frame Shift Del (DEL) | VAF 64/229 reads (28%) | catalogued as COSV99454570; called by mutect2, pindel, varscan2
- POM121L2 | c.2996G>T p.G999V | Missense Mutation (SNP) | VAF 167/506 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV66276924; called by muse, mutect2, varscan2
- PSG3 | c.958C>T p.R320C | Missense Mutation (SNP) | VAF 298/300 reads (99%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as rs372669757; called by muse, mutect2, varscan2
- SRP9 | c.31A>G p.S11G | Missense Mutation (SNP) | VAF 303/675 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.183); catalogued as rs759341292; called by muse, mutect2, varscan2
- TAF6L | c.23G>A p.R8Q | Missense Mutation (SNP) | VAF 207/653 reads (32%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.886); catalogued as rs1206668065, COSV53667788; called by muse, mutect2, varscan2
- ZNF431 | c.622A>G p.K208E | Missense Mutation (SNP) | VAF 93/162 reads (57%) | SIFT tolerated (1); PolyPhen benign (0.04); catalogued as rs968395546, COSV60673074; called by muse, mutect2, varscan2
- ABCF1 | c.796G>A p.E266K (on ENST00000326195 / NM_001025091.2; = p.E228K on NM_001090.3) | Missense Mutation (SNP) | VAF 248/404 reads (61%) | SIFT tolerated (0.08); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ACSM6 | c.647A>C p.K216T | Missense Mutation (SNP) | VAF 14/486 reads (3%) | SIFT deleterious (0.04); PolyPhen benign (0.065); called by muse, mutect2
- AHNAK2 | c.14134T>C p.S4712P | Missense Mutation (SNP) | VAF 14/310 reads (5%) | SIFT tolerated (0.35); PolyPhen benign (0.041); called by muse, mutect2
- ARHGAP32 | c.1669G>A p.E557K (on ENST00000310343 / NM_001378025.1; = p.E208K on NM_014715.4) | Missense Mutation (SNP) | VAF 289/743 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- CAMSAP2 | c.3269A>C p.E1090A (on ENST00000236925 / NM_001297707.2; = p.E1079A on NM_203459.3) | Missense Mutation (SNP) | VAF 100/689 reads (15%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.938); called by muse, mutect2, varscan2
- CCDC17 | c.1663G>T p.A555S | Missense Mutation (SNP) | VAF 126/399 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); called by muse, mutect2, varscan2
- CNTNAP4 | c.1589C>A p.S530* | Nonsense Mutation (SNP) | VAF 293/468 reads (63%) | called by muse, mutect2, varscan2
- CRIP1 | c.199G>A p.G67R | Missense Mutation (SNP) | VAF 143/388 reads (37%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.929); called by muse, varscan2
- CSMD2 | c.7380G>T p.K2460N | Missense Mutation (SNP) | VAF 238/355 reads (67%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- DNAH11 | c.7340G>T p.G2447V | Missense Mutation (SNP) | VAF 31/422 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2
- FNTB | c.883C>G p.L295V | Missense Mutation (SNP) | VAF 200/543 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- MMP12 | c.717_728del p.Y240_V243del | In Frame Del (DEL) | VAF 84/606 reads (14%) | called by mutect2, pindel, varscan2
- OR14J1 | c.962T>A p.L321H | Missense Mutation (SNP) | VAF 81/238 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR4E1 | c.220G>T p.D74Y | Missense Mutation (SNP) | VAF 118/327 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RIMS2 | c.2527_2529del p.L843del (on ENST00000666250 / NM_001348490.2; = p.L651del on NM_014677.5 and 7 other RefSeq transcripts) | In Frame Del (DEL) | VAF 66/218 reads (30%) | called by pindel, varscan2
- SECISBP2 | c.767G>C p.R256T | Missense Mutation (SNP) | VAF 103/250 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- SKIDA1 | c.970G>C p.E324Q | Missense Mutation (SNP) | VAF 746/1290 reads (58%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.037); called by muse, varscan2
- SLC52A1 | c.173G>T p.G58V | Missense Mutation (SNP) | VAF 364/364 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TGFBI | c.1400T>C p.V467A | Missense Mutation (SNP) | VAF 121/323 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- TNN | c.418C>T p.R140C | Missense Mutation (SNP) | VAF 280/530 reads (53%) | SIFT tolerated (0.09); PolyPhen benign (0.112); called by muse, mutect2, varscan2
- VAV1 | c.322-1G>T p.X108_splice | Splice Site (SNP) | VAF 36/297 reads (12%) | called by muse, mutect2, varscan2
- ZBTB8OS | c.77_80del p.T26Kfs*50 | Frame Shift Del (DEL) | VAF 90/394 reads (23%) | called by mutect2, pindel, varscan2
- ZFHX4 | c.8419A>T p.N2807Y | Missense Mutation (SNP) | VAF 152/457 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF70 | c.130A>G p.M44V | Missense Mutation (SNP) | VAF 137/439 reads (31%) | SIFT tolerated (0.36); PolyPhen benign (0); called by muse, mutect2, varscan2
- BEST1 | c.471G>C p.L157= | Silent (SNP) | VAF 134/686 reads (20%) | called by muse, mutect2, varscan2
- BRD4 | c.2988C>T p.P996= | Silent (SNP) | VAF 434/827 reads (52%) | catalogued as rs758643407; called by muse, varscan2
- HELZ | c.5628G>A p.A1876= | Silent (SNP) | VAF 466/634 reads (74%) | catalogued as rs745477812; called by muse, mutect2, varscan2
- KIR2DL3 | c.597C>T p.F199= | Silent (SNP) | VAF 198/198 reads (100%) | catalogued as rs747953308; called by muse, mutect2, varscan2
- MPO | c.1347C>T p.I449= | Silent (SNP) | VAF 302/422 reads (72%) | catalogued as rs746831572, COSV56561153, COSV99832387; called by muse, mutect2, varscan2
- OR2G6 | c.543G>A p.V181= | Silent (SNP) | VAF 108/554 reads (19%) | called by muse, mutect2, varscan2
- ROBO2 | c.2094C>A p.V698= | Silent (SNP) | VAF 137/460 reads (30%) | catalogued as COSV59911199; called by muse, mutect2, varscan2
- SBNO2 | c.1245C>T p.R415= | Silent (SNP) | VAF 168/354 reads (47%) | catalogued as rs936448675; called by muse, mutect2, varscan2
- UPF2 | c.66A>G p.E22= | Silent (SNP) | VAF 277/528 reads (52%) | catalogued as rs1177603336; called by muse, mutect2, varscan2
- UTP14C | c.738C>T p.I246= | Silent (SNP) | VAF 35/330 reads (11%) | catalogued as COSV101584338; called by muse, mutect2, varscan2
- GALNT14 | c.129+23147_129+23148del | Intron (DEL) | VAF 171/411 reads (42%) | called by mutect2, pindel, varscan2
